Gene-level copy-number profile of tumor specimen TCGA-D8-A1JF-01A from TCGA case TCGA-D8-A1JF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79.9 years (29,199 days).
Specimen TCGA-D8-A1JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b93cb7b4-ce63-4f54-864e-f271f86c0781.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccdc1ff1-4b73-44c1-98fd-0fe7b83ce78d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 148; copy number 2: 12,175; copy number 3: 22,449; copy number 4: 14,316; copy number 5: 6,767; copy number 6: 1,342; copy number 7: 25; copy number 8: 1,835; copy number 9: 720; copy number 11: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JF-01A-11D-A13J-01): tumor purity 0.49, ploidy 3.6, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,623 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:3,144,628–3,179,727, 2 genes, copy number 8: CRBN, AC024060.2.
- chr5:13,553,654–14,532,128, 6 genes, copy number 9: NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr6:3,585,101–7,620,878, 94 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr6:9,596,110–10,478,502, 15 genes, copy number 9 (within-gene range 5–9): OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522.
- chr8:150,584–145,066,685, 2,481 genes, copy number 8–11 (broad region; genes not listed).
- chr11:56,208,985–56,501,271, 25 genes, copy number 7: OR8J2, OR5T2, OR5T3, OR5T1, OR8H1, OR8I1P, OR8K3, FAM8A2P, OR8K2P, OR8K1, OR8J1, RPL5P29, OR8U1, OR8L1P, OR5AL2P, OR5AL1, OR5R1, OR5M4P, AP002512.3, OR5M9, OR5M3, OR5M2P, OR5M8, AP002512.1, OR5M7P.

Autosomal genes at a single copy (total copy number 1): 148. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
